MMRF case MMRF_1451 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/16c8cf8e-ea82-4185-9349-5218c03f0c75

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 154 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.3 years (23,860 days); ISS stage: III; Days to last known disease status: 154 days; Days to last follow up: 154 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 154 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 147 days; Days to treatment end: 154 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 154.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1457 mg/dL; Immunoglobulin G 4.81 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 21 µg/mL; Lactate Dehydrogenase 4.75 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 309 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.53 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 7.15 mmol/L; C-Reactive Protein 2.1 mg/dL.
- Day 91 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 527 mg/dL; Immunoglobulin G 3.4 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 13.2 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 7.54 mmol/L.
- Day 152 (ECOG 5): Serum Free Immunoglobulin Light Chain, Kappa 0.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.2 mg/dL; Immunoglobulin G 2.59 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 4.28 mmol/L; Leukocytes 0.5 ×10⁹/L; Absolute Neutrophil 0.1 ×10⁹/L; Platelets 20 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 8.31 mmol/L.

Other clinical attributes
- Day -5: Weight: 77 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1451_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1451_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
